Surgical pathology report (de-identified scan), TCGA case TCGA-B8-4154, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-4154-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

Surgical Pathology Report

Accession #:

Diagnosis:

A: Kidney, left, biopsy

- Renal cell carcinoma, clear cell type, Fuhrman grade 2 of 4.

B: Kidney, left, radical nephrectomy

Histologic tumor type/subtype: renal cell carcinoma, clear cell type

Histologic grade (if applicable): Fuhrman grade 2 of 4

Tumor size (greatest dimension): 2 cm

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: negative for carcinoma

Gerota' s fascia: negative for carcinoma

Renal vein: negative for carcinoma

Ureter: negative for carcinoma

Venous (large vessel): negative for carcinoma

Lymphatic (small vessel): negative for carcinoma

Histologic assessment of surgical margins:

Perirenal adipose tissue: negative for carcinoma

Gerota' s fascia: negative for carcinoma

Renal vein: negative for carcinoma

Renal artery: negative for carcinoma

Ureter: negative for carcinoma

[page 2 of 4]
Adrenal gland: Not submitted

Lymph nodes: none identified

Other significant findings: focal glomerulosclerosis

AJCC Staging:

pT1a

pNx

pMx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Intraoperative Consult Diagnosis:

Frozen section is requested by [REDACTED]

FSA1: Kidney, left, biopsy

- Consistent with clear cell carcinoma

- [REDACTED]

Diagnoses were made by [REDACTED]

Frozen Section Pathologist:

Clinical History:

The patient is a with a 3 cm central renal mass.

Gross Description:

Specimen A is received in an appropriately labeled container, additionally labeled "left kidney tumor biopsy". At the time of frozen section, the specimen was noted to measure 1.2 x 0.8 x 0.3 cm. It was a red/tan soft tissue entirely submitted as [REDACTED] [REDACTED]

Specimen B is received in an appropriately labeled container, additionally labeled "left kidney".

Specimen fixation: Formalin

Type of specimen: Left radical nephrectomy

Side of specimen: Left

[page 3 of 4]
Size and weight of specimen: The specimen weighs 250 grams; specimen measures 16 x 11 x 6 cm overall; the kidney measures 10 x 5 x 4 cm.

Orientation: The specimen was inked blue and previously opened through the hilum in the operating room.

Presence/absence of adrenal gland: Absent

Tumor description/site: The tumor has a central location involving the renal medulla with a pushing border into the renal pelvis (no definitive invasion into the sinus fat is identified); the tumor is firm, orange/yellow with visible areas of hemorrhage; the tumor has an overall lobulated appearance; areas of necrosis are not grossly identified.

Tumor size: 2 x 2 x 2 cm

Presence/absence of multicentricity: The tumor is unifocal.

Confinement/non-confinement to the kidney: The tumor is confined to the kidney.

Extent of invasion:

Perirenal adipose tissue: The tumor does not involve perirenal adipose tissue.

Gerota's fascia: Not grossly involved.

Renal vein: Not grossly involved.

Ureter: Not grossly involved.

Other organs: Not applicable.

Surgical margins:

Perirenal adipose tissue: Negative

Renal vein: Negative

Renal artery: Negative

Ureter: Negative

Description of kidney away from tumor: The kidney surrounding the tumor has a normal ratio of cortex to medulla without specific pathologic abnormality.

Lymph nodes (hilar): The perirenal fat is palpated for lymph nodes, but none are identified.

Other significant findings: None

Tissue submitted for special investigations: Tumor and

[page 4 of 4]
normal tissue are submitted to tissue procurement for special investigation.

Digital photograph taken: No digital picture is taken.

Block summary:

- B1 - Vascular and ureteral margins
- B2 - Tumor with extension into pelvis with closely adjacent vascular structure
- B3 - Tumor with extension into pelvis with closely adjacent vascular structure
- B4 - Tumor with hemorrhage and adjacent hilar adipose tissue and cortex
- B5 - Tumor with closest approach to cortical surface
- B6 - Additional section of tumor with approach to cortical surface
- B7 - Additional section of tumor with approach to cortical surface
- B8 - Structures abutting neoplasm in hilum
- B9 - Normal kidney

Source: NCI Genomic Data Commons file 1b27429f-3da9-4a9c-925c-8939d8869237 (TCGA-B8-4154.A01DB58E-8B1F-44A8-B332-02779D4438E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).